Surgical pathology report (de-identified scan), TCGA case TCGA-XR-A8TG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XR-A8TG-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0 8170/3
JW 11/29/14

Nature of material: Liver

Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received 2 vials, identified as follows:

-Liver: liver fragment, wedge-shaped, measuring 7.5 x 6.0 x 1.5 cm and weighing 61.0 g. Its external surface shows capsule with opaque and rough appearance due to the presence of multiple micro undulations. It shows a softened and whitish lesion of circular shape with a larger diameter 2.5 cm, 1.0 cm away from the surgical resection margin. The remaining portions of hepatic parenchyma show hardened, brownish and a cirrhotic pattern.

-Gallbladder: gallbladder, previously opened in its longer axis, measuring 7.5 x 3.5 x 1.0 cm. It is accompanied by the cystic duct stump, measuring 1.5 cm long and 0.6 cm in diameter. Its outer surface is smooth and greenish-brown. The wall is gray and homogeneous, while the mucosa shows velvety appearance and yellowish coloring, with polypoid aspect folds. It was not observed stones.

MICROSCOPY

Description associated with the diagnosis.

DIAGNOSTIC

Product of partial hepatectomy and cholecystectomy:

-Hepatocellular carcinoma of multinodular pattern with well differentiated (grade II of Edmonson-Steiner - in 40% of the lesion) and poorly differentiated (grade IV of Edmonson-Steiner - in 60% of the lesion) areas. The lesion shows solid, trabecular and small cells morphologic pattern, with higher measure of 2.5 cm and focally infiltrating liver capsule.

-Vascular invasion and angiolymphatic embolization undetected.

-Adjacent hepatic parenchyma with micronodular cirrhosis, associated with moderate necroinflammatory activity. C virus infection, according to clinical data.

-Free surgical margins.

-Gallbladder with tiny and polypoid projections in mucosa, associated with xanthomized macrophage accumulation (cholesterol polyps): Morphological features are compatible with cholesterosis. No signs of malignancy, in the gallbladder.

-Pathological staging (TNM - 7th ed.): pT1 pNx.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Site Discrepancy		
Site, Metastasis, and History		

Source: NCI Genomic Data Commons file 0237f636-8204-43f4-a453-fb5810180516 (TCGA-XR-A8TG.B6CBB321-E73F-4A24-8557-E10E94B2B8C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).